Gene-level copy-number profile of tumor specimen TCGA-ER-A19H-06A from TCGA case TCGA-ER-A19H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.7 years (18,508 days).
Specimen TCGA-ER-A19H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.13f9fcb5-e501-475f-a727-625e29ffb905.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90dae7db-d509-4c06-a749-102135aa6f48

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 116; copy number 2: 20,476; copy number 3: 26,395; copy number 4: 12,013; copy number 5: 721; copy number 6: 9; copy number 7: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19H-06A-12D-A194-01): tumor purity 0.67, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 88 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:13,891,229–14,071,380, 3 genes, copy number 7 (within-gene range 5–7): ETV1, Y_RNA, RPL6P21.
- chr7:14,190,795–14,192,157, 1 gene, copy number 7: EEF1A1P26.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 7: TRGV5P, TRGV5, TRGV4.
- chr7:105,110,704–105,399,308, 1 gene, copy number 7 (within-gene range 4–7): SRPK2.
- chr7:105,204,600–108,995,029, 65 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 116. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
